Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A6RI, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A6RI-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

Collection Date:

PART 1: ESOPHAGUS, PARTIAL ESOPHAGOGASTRECTOMY -

- A. INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED, 3.8 CM, LOCATED AT GASTROESOPHAGEAL JUNCTION.
- B. ADENOCARCINOMA ARISES IN A BACKGROUND OF BARRETT'S MUCOSA WITH HIGH GRADE DYSPLASIA AND INVAPES INTO THE SUBMUCOSA.
- C. PROXIMAL (ESOPHAGEAL), DISTAL (GASTRIC) AND CIRCUMFERENTIAL (ADVENTITIAL) RESECTION MARGINS ARE NEGATIVE FOR MALIGNANCY.
- D. ANGIOLYMPHATIC INVASION PRESENT.
- E. PERINEURAL INVASION ABSENT.
- F. BACKGROUND ESOPHAUS WITH BARRETT'S MUCOSA.
- G. BACKGROUND STOMACH WITH INTESTINAL METAPLASIA AND MILD CHRONIC GASTRITIS.
- H. TOTAL THIRTEEN LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/13; see also parts 2 through 6).
- I. PATHOLOGIC STAGE= pT1bN0.

PART 2: GASTROESOPHAGEAL FAT, EXCISION -

SEVEN LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/7).

PART 3: LYMPH NODE, LEVEL 7, BIOPSY -

ONE ANTHRACOTIC LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 4: LYMPH NODE, SUBCARINAL, BIOPSY -

ONE ANTHRACOTIC LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 5: LYMPH NODE, MID PARAESOPHAGEAL, BIOPSY -

ONE ANTHRACOTIC LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 6: LYMPH NODE, DISTAL PARAESOPHAGEAL, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 7: GASTRIC RINGS, EXCISION -

- A. PORTION OF STOMACH LINED BY OXYNTIC MUCOSA, NEGATIVE FOR MALIGNANCY.
- B. PORTION OF ESOPHAGUS LINED BY REACTIVE SQUAMOUS MUCOSA, NEGATIVE FOR MALIGNANCY.

PART 8: FINAL GASTRIC MARGINS, EXCISION -

PORTION OF STOMACH LINED BY OXYNTIC MUCOSA, NEGATIVE FOR MALIGNANCY.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE:

Esophagogastrectomy

TUMOR SITE:

Esophagogastric junction (EGJ) region (tumor involves EGJ and epicenter within 5cm of EGJ)

TUMOR SIZE:

Greatest dimension: 3.8 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE:

Adenocarcinoma

HISTOLOGIC GRADE:

G2

PATHOLOGIC STAGING (pTNM)

pT1b

pN0

Number of lymph nodes examined: 13

Number of lymph nodes involved: 0

pM Not applicable

PRIOR TREATMENT:

No prior treatment

MARGINS

Proximal margin uninvolved by dysplasia

Distal margin uninvolved by dysplasia

Circumferential (adventitial) margin uninvolved by invasive carcinoma

Present

ANGIOLYMPHATIC INVASION:

ADDITIONAL PATHOLOGIC FINDINGS:

Intestinal metaplasia (Barrett's esophagus)

High grade dysplasia

Gastritis (type): Mild chronic inactive.

COMPREHENSIVE THERANOSTIC SUMMARY

IMMUNOHISTOCHEMISTRY:

Her2:

RESULTS

NEGATIVE (0)

**See Special Procedure reports below for additional details and background on
In situ/FISH and/or testing as pertinent**

[page 2 of 2]
SPECIAL PROCEDURES:

In Situ Procedure

Interpretation

INTERPRETATION GUIDELINES AND PROBE/CLONE INFORMATION:

FISH:

Probe: **HER2** DNA Probe

Probe Description: The **HER2** DNA probe is a 190 Kb directly labeled fluorescent DNA probe specific for the **HER2** gene locus. The CEP 17 DNA probe is a 5.4 Kb directly labeled fluorescent DNA probe specific for the alpha satellite DNA sequence at the centromeric region of chromosome 17. The probes are pre-mixed and pre-denatured in hybridization buffer.

Interpretation:

HER2 negative: HER2 gene/chromosome 17 ratio less than 2.0
HER2 positive: HER2 gene/chromosome 17 ratio greater than 2.0

Results should be considered along with other clinical information.

The [redacted] has modified the suggested manufacturer protocol for **HER2** FISH testing. The modifications have been tested and validated. The modifications are as follows: Slides are deparaffinized in [redacted] Tissue is digested in protease 31 minutes; Tissue and probe are co-denatured at 90 C for 12 minutes; Paraffin pretreatment reagents and control slides are prepared in house. Amplified, non-amplified, and internal (centromere 17) controls were used in the testing. The laboratory takes responsibility for the test performance.

FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the **HER2** and the **CEP17** probes.

IHC:

anti-HER-2/neu (4B5) Rabbit Monoclonal Primary Antibody

Tumors are considered POSITIVE if they show HER2 protein over-expression (3+) by IHC.

IHC scoring for HER2 in gastric and GE junction cancer by type of diagnostic specimen:

SCORE SURGICAL SPECIMEN-STAINING PATTERN

NEGATIVE

0 No reactivity or membranous reactivity in <10% of tumor cells

1+ Faint/barely perceptible membranous reactivity in $\geq 10\%$ of tumor cells; cells are reactive only in part of their membrane

EQUIVOCAL

2+ Weak to moderate complete, basolateral or lateral membranous reactivity in $\geq 10\%$ of tumor cells

POSITIVE

3+ Strong complete, basolateral or lateral membranous reactivity in $\geq 10\%$ of tumor cells

BIOPSY SPECIMEN-STAINING PATTERN

NEGATIVE

0 No reactivity or no membranous reactivity in any (or <5 clustered) tumor cells

1+ Tumor cell cluster (≥ 5 cells) with a faint/barely perceptible membranous reactivity irrespective of percentage of tumor cells stained

EQUIVOCAL

2+ Tumor cell cluster (≥ 5 cells) with a weak to moderate complete, basolateral or lateral membranous reactivity irrespective of percentage of tumor cells stained

POSITIVE

3+ Tumor cell cluster (≥ 5 cells) with a strong complete, basolateral or lateral membranous reactivity irrespective of percentage of tumor cells stained

Results

HER2 IMMUNOPEROXIDASE STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE.

IHC score: 0.

Source: NCI Genomic Data Commons file bc40500a-94a0-4d39-91da-5ea8f93e29e1 (TCGA-IN-A6RI.1F91F713-5737-41AE-A613-F61A3AEAA841.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).